Somatic mutation profile of tumor specimen TARGET-10-PARDLR-09A (aliquot TARGET-10-PARDLR-09A-01D) from TARGET case TARGET-10-PARDLR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.3 years (3,042 days).
Specimen TARGET-10-PARDLR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1d6c2af-0866-4344-be12-90ba3a760af3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDLR-14A (Bone Marrow Normal), aliquot TARGET-10-PARDLR-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca353f68-367d-4624-96ed-3a36e23d9aa5

The open-access MAF lists 25 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Intron 3, 5'UTR 1, 3'Flank 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP11B1 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs104894068, CM970407, COSV52827729; ClinVar: pathogenic; called by muse, mutect2
- BRINP3 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757799162, COSV66543802; called by muse, varscan2
- CDH8 | c.2146C>A p.P716T | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.828); catalogued as COSV54876173; called by muse, mutect2, varscan2
- FANK1 | c.99G>T p.K33N | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV64156533; called by muse, mutect2, varscan2
- KDM6A | c.1065G>A p.W355* | Nonsense Mutation (SNP) | VAF 59/121 reads (49%) | catalogued as COSV65038273; called by muse, mutect2, varscan2
- MFSD3 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.87); catalogued as rs868109098; called by muse, mutect2
- PCDHA11 | c.2188G>A p.A730T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as COSV56494142; called by muse, mutect2, varscan2
- PIEZO2 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs1338267898; called by muse, mutect2, varscan2
- TLR5 | c.796G>T p.G266C | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199532936; called by muse, mutect2, varscan2
- ASB13 | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- CD58 | c.269T>A p.L90H | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CKAP4 | c.1735G>T p.G579C | Missense Mutation (SNP) | VAF 83/185 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- PTPRM | c.2549G>A p.S850N | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TET2 | c.2232G>T p.Q744H | Missense Mutation (SNP) | VAF 82/156 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ENTR1 | c.330T>C p.S110= (on ENST00000357365 / NM_001039707.2; = p.S87= on NM_006643.4) | Silent (SNP) | VAF 32/68 reads (47%) | called by muse, mutect2, varscan2
- IQCA1 | c.882G>A p.K294= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as COSV99608316; called by muse, mutect2, varscan2
- METTL16 | c.999G>A p.S333= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as rs781603857, COSV54015615; called by muse, mutect2, varscan2
- PCDHB15 | c.1590C>T p.R530= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- SPTB | c.1377C>T p.A459= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as rs146670683; called by muse, mutect2, varscan2
- CAGE1 | c.-9T>A | 5'UTR (SNP) | VAF 29/141 reads (21%) | called by muse, mutect2, varscan2
- IGHV1-69D | chr14:106762091 ins GTCCA | 3'Flank (INS) | VAF 29/87 reads (33%) | called by mutect2, pindel, varscan2
- LINC00632 | n.104+1869G>T | Intron (SNP) | VAF 86/177 reads (49%) | called by muse, mutect2, varscan2
- NPHP3 | c.2311-22G>T | Intron (SNP) | VAF 25/88 reads (28%) | called by muse, mutect2, varscan2
- TACC2 | c.5972-117G>T | Intron (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- TGIF1P1 | n.451C>T | RNA (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
